CPTAC case C3L-09973 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9a1261ff-dd9d-4ed2-b4e9-e0124b0212f6

Demographics
Sex at birth: male; Race: white; Year of birth: 1959; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 63.2 years (23,073 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N3b; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 713 days (2.0 years); Progression or recurrence: yes; Days to recurrence: 495 days (1.4 years); Days to last follow up: 713 days (2.0 years); Tumor focality: Multifocal.
   Pathology details: Lymph node involvement: Positive; Lymph nodes positive: 19; Lymph nodes tested: 45.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 41 days; Days to treatment end: 71 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 627 days (1.7 years); Days to treatment end: 689 days (1.9 years); Treatment outcome: Partial Response.

Follow-up (2 entries)
- Days to follow up: 348 days; Disease response: Partial Response; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 713 days (2.0 years); Disease response: Partial Response; Karnofsky performance status: 90; ECOG performance status: 2.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-09973-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 1,033 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09973-21: Section location: whole stomach; Percent tumor nuclei: 50; Percent necrosis: 1.
- Sample C3L-09973-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
